Somatic mutation profile of tumor specimen TCGA-CN-5364-01A (aliquot TCGA-CN-5364-01A-01D-1434-08) from TCGA case TCGA-CN-5364, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 55.7 years (20,362 days).
Specimen TCGA-CN-5364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba5b4413-bee9-4561-a2f7-66ae864ec0d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5364-10A (Blood Derived Normal), aliquot TCGA-CN-5364-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef872dba-0baa-4305-92b0-268fb962b569

The open-access MAF lists 148 somatic variants for this specimen: 124 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 20, Nonsense Mutation 14, Frame Shift Ins 4, In Frame Del 3, Splice Site 2, Splice Region 2, RNA 2, Frame Shift Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLST | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270341616, COSV53166055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99397333; called by muse, mutect2
- APC | c.2659A>T p.I887F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99967030; called by muse, mutect2, varscan2
- ARHGEF18 | c.3356_3358del p.F1119del (on ENST00000359920 / NM_001130955.2; = p.F1015del on NM_015318.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs1351546343; called by pindel, varscan2
- ARL13B | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100115345; called by muse, mutect2, varscan2
- ASNS | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99446143; called by muse, mutect2, varscan2
- ATAD2B | c.2831T>A p.L944* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99477392; called by muse, mutect2, varscan2
- ATM | c.8697C>G p.I2899M | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1333079704, COSV53770059, COSV99589027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2C1 | c.2554A>C p.I852L | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100146582; called by muse, mutect2, varscan2
- BAP1 | c.1756A>C p.I586L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1553644740, COSV99963770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAR3 | c.1943C>G p.S648* | Nonsense Mutation (SNP) | VAF 27/164 reads (16%) | catalogued as COSV99550595; called by muse, mutect2, varscan2
- C20orf194 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV99330561; called by muse, mutect2, varscan2
- CENPJ | c.3774T>G p.D1258E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99692808; called by muse, mutect2, varscan2
- CEP250 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100698866; called by muse, mutect2, varscan2
- CHAF1B | c.1030A>T p.I344L | Missense Mutation (SNP) | VAF 73/331 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100023456; called by muse, mutect2, varscan2
- CHD9 | c.8584C>T p.P2862S (on ENST00000398510 / NM_001382353.1; = p.P2846S on NM_025134.7) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as COSV99529022; called by muse, mutect2, varscan2
- CLK1 | c.278A>T p.H93L | Missense Mutation (SNP) | VAF 75/318 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV58433208; called by muse, mutect2, varscan2
- COL14A1 | c.636G>C p.L212F | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99918741; called by muse, mutect2, varscan2
- COL22A1 | c.3001C>A p.L1001I | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV57332797; called by muse, mutect2, varscan2
- CPNE8 | c.403A>T p.I135L | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58841626; called by muse, mutect2, varscan2
- CPXCR1 | c.150C>A p.N50K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV52161901; called by muse, mutect2, varscan2
- CXXC4 | c.756C>G p.I252M | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV67295786, COSV67296233; called by muse, mutect2, varscan2
- DBF4B | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as COSV100154434; called by muse, mutect2, varscan2
- DICER1 | c.5186C>A p.P1729Q | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58623841; called by muse, mutect2
- DPH1 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV53984300; called by muse, mutect2, varscan2
- DPP10 | c.2285C>A p.S762Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100062347, COSV59680781; called by muse, mutect2, varscan2
- EPHA7 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as rs1300929218, COSV100992397, COSV65169176; called by muse, mutect2, varscan2
- ESX1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as rs375606449, COSV101006428; called by muse, mutect2, varscan2
- EXOC8 | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99149477; called by muse, mutect2, varscan2
- FAM83C | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.335); catalogued as COSV65582764; called by muse, varscan2
- FAT4 | c.12730G>T p.G4244C | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58680152; called by muse, mutect2, varscan2
- FMN2 | c.4514A>T p.N1505I | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60426850; called by muse, mutect2, varscan2
- FSD1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV99696694; called by muse, mutect2, varscan2
- GFOD2 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as COSV99263484; called by muse, mutect2, varscan2
- GLRA3 | c.73T>C p.L25= | Splice Region (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99927353; called by muse, mutect2, varscan2
- GNPTAB | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV100171918; called by muse, mutect2, varscan2
- HDX | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV52975579; called by muse, mutect2, varscan2
- HIVEP2 | c.5897C>A p.S1966Y | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99172928; called by muse, mutect2, varscan2
- HOXD3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.059); catalogued as COSV99980047; called by muse, mutect2, varscan2
- HSPA1L | c.1166A>G p.K389R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.297); catalogued as COSV100989368; called by muse, mutect2, varscan2
- ITPRID2 | c.642A>G p.I214M | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57470981; called by muse, mutect2, varscan2
- IWS1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.972); catalogued as COSV54866925; called by muse, mutect2, varscan2
- KCNA4 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV60251690; called by muse, mutect2, varscan2
- KDM5B | c.1517A>T p.Y506F | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52506895; called by muse, mutect2, varscan2
- LCK | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100287587; called by muse, varscan2
- LCK | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.556); catalogued as COSV100287589; called by muse, varscan2
- LCK | c.1042-1G>A p.X348_splice | Splice Site (SNP) | VAF 21/179 reads (12%) | catalogued as COSV60739363; called by muse, mutect2, varscan2
- LMX1A | c.989-1G>A p.X330_splice | Splice Site (SNP) | VAF 19/104 reads (18%) | catalogued as COSV54216424, COSV99672641; called by muse, mutect2, varscan2
- LPP | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | catalogued as COSV100446701; called by muse, mutect2
- LRRTM1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.587); catalogued as COSV99702241; called by muse, mutect2, varscan2
- LSAMP | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.066); catalogued as COSV61286188, COSV61301500; called by muse, mutect2, varscan2
- MBD5 | c.3886C>T p.R1296* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV101290029; called by muse, mutect2, varscan2
- MCC | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | catalogued as rs1357719104, COSV100202423, COSV56724381; called by muse, mutect2
- MCCC2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.021); catalogued as COSV100040083; called by muse, mutect2
- MPI | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469654026, COSV60396658; called by muse, mutect2, varscan2
- MRPL9 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 44/219 reads (20%) | catalogued as COSV100162496; called by muse, mutect2, varscan2
- MUS81 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100337224; called by muse, mutect2
- NAALADL1 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.026); catalogued as rs1452580337, COSV60523540; called by muse, mutect2, varscan2
- NEUROG1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100130767; called by muse, mutect2, varscan2
- NMT2 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV65381788; called by muse, mutect2, varscan2
- NPAS4 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 23/422 reads (5%) | catalogued as COSV100214947; called by muse, mutect2
- NUP214 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1480024178, COSV63908882; called by muse, mutect2, varscan2
- OLFM3 | c.1090C>T p.Q364* (on ENST00000338858 / NM_001288821.1; = p.Q344* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV100129207; called by muse, mutect2, varscan2
- OR10T2 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV57780916; called by muse, mutect2, varscan2
- OR1L4 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99413845; called by muse, mutect2
- OR5L1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs745385243, COSV61733573, COSV61734273, COSV61735834; called by muse, mutect2, varscan2
- OR8J1 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57317748, COSV57319354; called by muse, mutect2, varscan2
- OSBPL1A | c.2748G>A p.T916= (on ENST00000319481 / NM_080597.4; = p.T403= on NM_018030.4) | Splice Region (SNP) | VAF 80/379 reads (21%) | catalogued as rs143353189; called by muse, mutect2, varscan2
- PAPPA2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV62776503; called by muse, mutect2, varscan2
- PARP16 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs756312315, COSV99975391; called by muse, mutect2, varscan2
- PCDH15 | c.4048C>T p.R1350C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138398244, COSV57293561; called by muse, mutect2, varscan2
- PCLO | c.6812C>A p.S2271Y | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as COSV61628376; called by muse, mutect2, varscan2
- PEG3 | c.4062T>A p.H1354Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV55630812; called by muse, mutect2, varscan2
- PIBF1 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58322297; called by muse, mutect2, varscan2
- PKN1 | c.1373A>T p.H458L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54396974; called by muse, mutect2, varscan2
- PLAAT4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV55373046; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs779738378, COSV99461142; called by muse, varscan2
- PPCS | c.804del p.F268Lfs*3 | Frame Shift Del (DEL) | VAF 24/208 reads (12%) | catalogued as COSV100999490; called by mutect2, varscan2
- PRRC2C | c.2452G>C p.E818Q (on ENST00000367742; = p.E816Q on NM_015172.4) | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.922); catalogued as COSV100145058, COSV58900778; called by muse, mutect2
- PTPRD | c.332C>A p.T111N | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV100644191; called by muse, mutect2, varscan2
- PTPRF | c.1681T>C p.F561L | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV63444331; called by muse, mutect2, varscan2
- RFX3 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100174880; called by muse, mutect2, varscan2
- RIC1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV99317045; called by muse, mutect2, varscan2
- RNH1 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV57277902; called by muse, mutect2, varscan2
- ROS1 | c.6443G>T p.G2148V | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100876896, COSV63851575; called by muse, mutect2, varscan2
- S1PR2 | c.118A>T p.I40F | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58485313; called by muse, mutect2, varscan2
- SETX | c.7364A>G p.Y2455C | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778210918, COSV56383115; called by muse, mutect2, varscan2
- SHANK1 | c.6443G>A p.R2148H | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1259178592, COSV53242336; called by muse, mutect2, varscan2
- SLC2A12 | c.1665C>A p.C555* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV51599527; called by muse, mutect2, varscan2
- SLC7A14 | c.1307A>G p.D436G | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV51580690; called by muse, mutect2, varscan2
- SLC7A6OS | c.351C>A p.S117R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV99862305; called by muse, mutect2, varscan2
- SLC9A1 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 121/498 reads (24%) | catalogued as COSV56052849; called by muse, mutect2, varscan2
- SLC9A3R1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs773559482, COSV99379967; called by muse, mutect2, varscan2
- SMARCA2 | c.2542A>T p.M848L | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV61806519; called by muse, mutect2, varscan2
- SNX8 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99770746; called by muse, mutect2, varscan2
- SPHKAP | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs1356113538, COSV100763913, COSV60875513; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 17/93 reads (18%) | PolyPhen benign (0.007); catalogued as COSV100602586; called by muse, mutect2, varscan2
- STX19 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100115347; called by muse, mutect2, varscan2
- TFAP2A | c.730G>A p.E244K (on ENST00000482890; = p.E236K on NM_001032280.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs151344526, CM110101, COSV100116730, COSV100116770; called by muse, mutect2, varscan2
- TLR5 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60558675; called by muse, mutect2, varscan2
- TNKS2 | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100861050; called by muse, mutect2, varscan2
- TP63 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53201679, COSV53221781; called by muse, mutect2, varscan2
- TTLL4 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99293187, COSV99293218; called by muse, mutect2, varscan2
- UNC13B | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs781007943, COSV61468164; called by muse, mutect2, varscan2
- WDR47 | c.403A>G p.S135G | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV63057700; called by muse, mutect2, varscan2
- XPNPEP2 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV64367853; called by muse, mutect2, varscan2
- XPOT | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.339); catalogued as rs752226938, COSV100225450; called by muse, mutect2, varscan2
- ZCCHC8 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as COSV60317962; called by muse, mutect2, varscan2
- ZFPM1 | c.2953A>T p.S985C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100128331; called by muse, mutect2, varscan2
- ZFYVE16 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100566313; called by muse, mutect2, varscan2
- ZNF253 | c.1466T>C p.L489S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV63036905; called by muse, mutect2, varscan2
- ZNF536 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62825548; called by muse, mutect2, varscan2
- ZNF667 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as COSV52633186; called by muse, mutect2, varscan2
- ZNF883 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV101432548, COSV71309149; called by muse, mutect2, varscan2
- FBXO11 | c.2713_2714dup p.T906Lfs*15 (on ENST00000403359 / NM_001190274.2; = p.T822Lfs*15 on NM_025133.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 35/183 reads (19%) | called by mutect2, pindel, varscan2
- FHOD1 | c.873_879dup p.F294Gfs*29 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | called by mutect2, varscan2
- GRIK2 | c.1120_1146del p.R374_G382del | In Frame Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel
- HAVCR2 | c.559_585del p.R187_S195del | In Frame Del (DEL) | VAF 22/134 reads (16%) | called by muse*, mutect2, varscan2*
- IGHG4 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- TBRG4 | c.203dup p.E69Rfs*45 | Frame Shift Ins (INS) | VAF 33/151 reads (22%) | called by mutect2, pindel, varscan2
- TMEM63A | c.1238dup p.Q414Pfs*37 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- USP32 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2
- AMER1 | c.1386A>G p.E462= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV57659171; called by muse, mutect2, varscan2
- ANTKMT | c.630C>T p.S210= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99557334; called by muse, mutect2
- CISH | c.721C>T p.L241= (on ENST00000348721 / NM_145071.4; = p.L258= on NM_013324.6) | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV62294774; called by muse, mutect2, varscan2
- CRYBG2 | c.159G>A p.E53= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- DOCK9 | c.5058C>G p.V1686= (on ENST00000376460 / NM_001366676.2; = p.V1687= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV59625749; called by muse, mutect2, varscan2
- FERMT3 | c.1953G>A p.E651= (on ENST00000279227 / NM_178443.3; = p.E647= on NM_031471.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV54173102; called by muse, mutect2, varscan2
- FIGNL1 | c.1764C>T p.L588= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as COSV100794878; called by muse, mutect2, varscan2
- FRMD3 | c.126G>T p.S42= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100418525; called by muse, mutect2
- HMCN1 | c.8007C>T p.I2669= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV54893170; called by muse, mutect2, varscan2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2
- KBTBD4 | c.1158G>A p.E386= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV58597028; called by muse, mutect2, varscan2
- MAP3K13 | c.1998C>T p.C666= | Silent (SNP) | VAF 133/314 reads (42%) | catalogued as rs759220118, COSV53987075; called by muse, mutect2, varscan2
- NDST4 | c.1956C>T p.F652= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs528525620, COSV52109529; called by muse, mutect2
- PCDHA1 | c.1323G>T p.V441= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV100974336; called by muse, mutect2
- SCN9A | c.1785G>A p.Q595= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV57600863; called by muse, mutect2, varscan2
- SEMA3C | c.495C>T p.R165= | Silent (SNP) | VAF 25/177 reads (14%) | catalogued as COSV54844794; called by muse, mutect2, varscan2
- SH3RF1 | c.1389A>G p.E463= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs1358058432, COSV52920031; called by muse, mutect2, varscan2
- SKAP2 | c.336A>G p.Q112= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100591841, COSV61725511; called by muse, mutect2, varscan2
- SPEN | c.727C>A p.R243= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV65360595; called by muse, mutect2, varscan2
- ZNF264 | c.1074C>T p.L358= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as COSV54040767; called by muse, mutect2, varscan2
- POM121 | chr7:72949921 ins C | 3'Flank (INS) | VAF 21/82 reads (26%) | called by mutect2, varscan2
- SLC38A10 | c.2065+218dup | Intron (INS) | VAF 6/40 reads (15%) | catalogued as rs142504417, COSV55842552, COSV99917876; called by pindel, varscan2
- SNORA60 | n.47A>G | RNA (SNP) | VAF 85/389 reads (22%) | catalogued as rs1241226139; called by muse, mutect2, varscan2
- SNORD109A | n.35G>A | RNA (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
